Somatic mutation profile of tumor specimen TARGET-10-PARDWE-03A (aliquot TARGET-10-PARDWE-03A-01D) from TARGET case TARGET-10-PARDWE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.3 years (6,685 days).
Specimen TARGET-10-PARDWE-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cea42268-3cba-4b05-8990-24dd1f3a4dda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDWE-10A (Blood Derived Normal), aliquot TARGET-10-PARDWE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45d2977a-72ea-4e88-b16f-23f0988743d7

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Frame Shift Ins 2, RNA 1, Splice Site 1, Silent 1, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV55883008; called by muse, mutect2, varscan2
- ARHGEF2 | c.2861G>A p.R954H (on ENST00000361247 / NM_001162383.2; = p.R926H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.033); catalogued as rs1339157141, COSV58108073; called by muse, mutect2, varscan2
- GRHL2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs375283208; called by muse, mutect2, varscan2
- JAK2 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV67586420; called by muse, mutect2, varscan2
- KDM6A | c.3331delinsGA p.R1111Efs*40 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | catalogued as COSV65038074, COSV65038305, COSV65040911, COSV65042699; called by mutect2*, pindel, varscan2*
- MYOM1 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as rs766999180; called by muse, mutect2, varscan2
- NCAPD3 | c.3620C>A p.S1207Y | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV73187818, COSV73187965; called by muse, mutect2, varscan2
- SLCO5A1 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs369446842; called by muse, mutect2, varscan2
- TBX3 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV57473959, COSV57476630; called by muse, mutect2, varscan2
- UBE2D2 | c.120+2T>C p.X40_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV54077846; called by muse, mutect2
- ZDHHC11 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as rs201839956; called by muse, mutect2, varscan2
- ARHGAP28 | c.1499T>C p.V500A (on ENST00000383472 / NM_001366230.1; = p.V341A on NM_001010000.3) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- KDM6A | c.3330dup p.R1111Afs*40 | Frame Shift Ins (INS) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- TAF6L | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2
- TRDV2 | c.343del p.T115del | Frame Shift Del (DEL) | VAF 27/43 reads (63%) | called by pindel*, varscan2
- ZNF804B | c.2679C>T p.S893= | Silent (SNP) | VAF 74/140 reads (53%) | catalogued as rs757534983; called by muse, mutect2
- EPS15L1 | c.166-149C>G | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as rs1364843144; called by muse, mutect2
- HYDIN2 | n.12423G>A | RNA (SNP) | VAF 9/29 reads (31%) | catalogued as rs1239017298; called by muse, mutect2, varscan2
- PPP1R12C | c.*11C>T | 3'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- ROBO2 | c.3761-2465G>A | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, varscan2
